Gene-level copy-number profile of tumor specimen TCGA-24-2290-01A from TCGA case TCGA-24-2290, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Specified parts of peritoneum; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 56.2 years (20,530 days).
Specimen TCGA-24-2290-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.52fce37e-fd7f-4b44-81ae-b2a3253f8699.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-2290-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/36f7ed6c-f41e-4844-bdc1-67683b27c257

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 105; copy number 2: 16,034; copy number 3: 6,481; copy number 4: 29,470; copy number 5: 3,264; copy number 6: 3,313; copy number 7: 13; copy number 8: 1,121.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-2290-01A-01D-0704-01): tumor purity 0.81, ploidy 3.66, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:63,844,700–64,162,217, 6 genes (within-gene range 0–4): SRGAP1, RPL36AP41, AC079866.2, AC079866.1, AC020611.1, AC020611.2.
- chr12:89,353,798–89,418,559, 1 gene (within-gene range 0–2): AC010201.3.
- chr12:89,419,718–89,526,262, 4 genes: POC1B, CENPCP1, POC1B-GALNT4, GALNT4.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 105. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
